Somatic mutation profile of tumor specimen TARGET-20-PATEFH-09A (aliquot TARGET-20-PATEFH-09A-01D) from TARGET case TARGET-20-PATEFH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,922 days).
Specimen TARGET-20-PATEFH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdf7049a-a998-4107-838b-bfebb67558c4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATEFH-14A (Bone Marrow Normal), aliquot TARGET-20-PATEFH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea8fea51-d9b2-4ced-9439-2e76278dd127

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.939_940insAAGGACACCGACAAG p.K313_V314insKDTDK | In Frame Ins (INS) | VAF 21/56 reads (38%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- TRIM24 | c.2728C>T p.R910C (on ENST00000343526 / NM_015905.3; = p.R876C on NM_003852.4) | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58968992; called by muse, mutect2, varscan2
